Somatic mutation profile of tumor specimen ALCH-B359-TTP1-A (aliquot ALCH-B359-TTP1-A-6-0-D-A77P-36) from ALCHEMIST case ALCH-B359, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.8 years (27,694 days).
Specimen ALCH-B359-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74d40b38-f34f-4c55-abdb-149e46c98352.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B359-NB1-A (Blood Derived Normal), aliquot ALCH-B359-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78600f63-769a-4a50-837c-4f9059135c35

The open-access MAF lists 65 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 10, Intron 7, Nonsense Mutation 2, RNA 2, 3'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 20/180 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- ARHGEF17 | c.5885C>T p.P1962L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as COSV55235845; called by muse, mutect2
- GAS8 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs753171620, COSV51944089; called by mutect2, varscan2
- GFM1 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399036958; called by muse, mutect2
- HDAC1 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65191080; called by muse, mutect2
- MAP3K12 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as rs1290950496; called by muse, mutect2
- MRPL27 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as COSV56812385; called by muse, mutect2
- MYH7 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1318155896, COSV62516918; ClinVar: uncertain significance; called by muse, mutect2
- OR10AG1 | c.505T>A p.F169I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV56634458; called by muse, mutect2, varscan2
- POLR3A | c.2582C>G p.T861R | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100965580; called by muse, mutect2
- PROKR2 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750316537; called by muse, mutect2, varscan2
- RGS7 | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 42/354 reads (12%) | catalogued as COSV58541248; called by muse, mutect2, varscan2
- SLC12A4 | c.2056C>T p.H686Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1347036368; called by muse, mutect2, varscan2
- SLC35A2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1557043139, COSV54429521; called by muse, mutect2
- SLC38A6 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs768889619; called by muse, mutect2
- TMEM178A | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs759716501, COSV56143388; called by muse, mutect2, varscan2
- TRIP4 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201642923; called by muse, mutect2
- BID | c.403C>T p.H135Y (on ENST00000317361 / NM_197966.2; = p.H89Y on NM_001196.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.461); called by muse, mutect2
- CSMD3 | c.7214A>G p.E2405G (on ENST00000297405 / NM_001363185.1; = p.E2301G on NM_052900.3) | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- CSN1S2AP | n.45G>A | Splice Region (SNP) | VAF 19/273 reads (7%) | called by muse, mutect2
- CWC25 | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- EIF4A2 | c.76-1G>C p.X26_splice | Splice Site (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2, varscan2
- EMSY | c.2119C>T p.Q707* | Nonsense Mutation (SNP) | VAF 23/332 reads (7%) | called by muse, mutect2
- ESRP2 | c.1135G>C p.G379R (on ENST00000565858 / NM_001365264.1; = p.G369R on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCRLA | c.198G>T p.E66D (on ENST00000367959; = p.E43D on NM_032738.4) | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FER | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.26); called by muse, mutect2
- FZD6 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 29/499 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL38 | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- MYO1E | c.488G>C p.R163P | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLRP12 | c.2132C>G p.T711S | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.489); called by muse, mutect2
- NRN1L | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PDSS2 | c.835A>C p.M279L | Missense Mutation (SNP) | VAF 9/310 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- PFAS | c.1263C>G p.I421M | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- PFDN1 | c.246G>C p.E82D | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2
- PKLR | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- PRDM7 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRKCB | c.266C>G p.A89G | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.151); called by muse, mutect2
- RBM12 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SH3RF2 | c.857G>C p.R286P | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.41); called by muse, mutect2
- SIRPA | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2
- TCOF1 | c.2038C>G p.P680A (on ENST00000377797 / NM_001135243.1; = p.P603A on NM_000356.4) | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TMEM236 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2
- VPS13B | c.11006A>G p.N3669S | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.089); called by muse, mutect2
- VWA8 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZNF324 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- AASS | c.780G>T p.V260= | Silent (SNP) | VAF 37/284 reads (13%) | called by muse, mutect2, varscan2
- ALK | c.2622C>T p.S874= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs528315610, COSV66561513; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP17 | c.408G>A p.K136= | Silent (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- C2orf74 | c.84C>T p.I28= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as COSV67041465; called by muse, mutect2
- CCDC62 | c.813G>A p.A271= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as rs756265250, COSV53430813; called by muse, mutect2
- DZIP1 | c.1620A>T p.G540= (on ENST00000347108; = p.G521= on NM_014934.5) | Silent (SNP) | VAF 10/215 reads (5%) | called by muse, mutect2
- KCNA4 | c.1014C>T p.L338= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1041324909, COSV100069131, COSV60256240; called by mutect2, varscan2
- PCDHA5 | c.1533G>A p.A511= | Silent (SNP) | VAF 10/193 reads (5%) | catalogued as rs782147398; called by muse, mutect2
- RBM11 | c.219T>A p.I73= | Silent (SNP) | VAF 12/96 reads (13%) | called by mutect2, varscan2
- UPF1 | c.936G>A p.L312= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- C22orf34 | n.104C>A | RNA (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- C3orf18 | c.235-749G>A | Intron (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- COL21A1 | c.1813-523A>T | Intron (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- EFNA4 | c.*19C>T | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs567168153; called by muse, mutect2, varscan2
- GPR161 | c.-139+2248C>T | Intron (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- OBSCN | c.5138-414A>T | Intron (SNP) | VAF 12/135 reads (9%) | catalogued as rs747269789; called by muse, mutect2, varscan2
- RBFOX1 | c.318+139G>A | Intron (SNP) | VAF 11/239 reads (5%) | called by muse, mutect2
- SHISA6 | c.800-3827C>A | Intron (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- TK2 | c.63+979C>T | Intron (SNP) | VAF 12/165 reads (7%) | called by muse, mutect2
- TUBB8P7 | n.1422C>A | RNA (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
